Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7620, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7620-01A (Primary Tumor).

Pathology Report for Subject: [REDACTED]

Addendum Discussion: The MIB-1 labeling index ranges up to 24.4% in the most proliferative regions of tumor.

Addendum Diagnosis:

1-3. Left frontal brain tumor including enhancing nodule, anaplastic oligodendroglioma, WHO grade III. Calculated MIB-1 labeling index = 24.4%

Microscopic Description:

1-3. Sections demonstrate an oligodendroglioma characterized by a proliferation of neoplastic cells which resemble oligodendrocytes. The tumor cells exhibit prominent perinuclear halos, rounded hyperchromatic nuclei and few cellular processes. Overall, the tumor cells exhibit moderate to marked cytologic atypia. They are arranged in sheets and infiltrate gray and white matter. Microvascular proliferation is identified as well as areas of early necrosis. An isolated focus of discrete necrosis is present which may represent previous biopsy site. Numerous mitotic figures are present at up to eight mitoses per 10 high power fields. Microgemocytes are readily identified admixed throughout the tumor. Both microcalcifications and branching thin walled vessels, features characteristic of oligodendrogliomas, are readily identified. These histologic features are consistent with an anaplastic oligodendroglioma.

Source: NCI Genomic Data Commons file 875628df-977f-4e6d-96ae-7a316c0de22e (TCGA-HT-7620.4115A114-29B2-4F53-A7DF-FB4E60B3E76A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).